Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-5451, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-5451-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED] Report Status: Amend/Addenda
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

TCGA-CZ-5451

CASE: [REDACTED]

PATIENT: [REDACTED]

***** Added Report *****

PATHOLOGIC DIAGNOSIS:

- A. LEFT KIDNEY, RADICAL NEPHRECTOMY:
RENAL CELL CARCINOMA, CLEAR CELL TYPE (8.7 cm), Fuhrman grade III, unifocal, involving the lower pole.
No capsular extension identified.
Soft tissue, ureteral, and vascular margins negative for tumor.
Adrenal gland negative for tumor.
Cortical simple cysts (3.5 cm largest).
AJCC (5th edition classification T2 N0 Mx)
- B. SPECIMEN LABELED "10th RIB SEGMENT":
Bone, cartilage, and skeletal muscle, negative for tumor.
Maturing trilineage hematopoiesis
- C. SPECIMEN LABELED "REGIONAL NODE":
Thirteen (13) lymph nodes with negative for tumor.

CLINICAL DATA:

History: [REDACTED] with weight loss, fatigue found renal mass by CT.
Operation: Nephrectomy.
Operative Findings: Not provided.
Clinical Diagnosis: Renal mass by CT.

TISSUE SUBMITTED:

- A. (L) kidney
- B. 10th rib segment
- C. Regional node

GROSS DESCRIPTION:

The specimen is received fresh, in three parts, each labeled with the patients name and unit number.

Part A, labeled "1. L kidney", consists of a 1449 gm left nephrectomy specimen (26.0 x 11.5 x 8.5 cm) including kidney (18.5 x 8.0 x 7.0 cm), ureter (8.2 cm in length x 0.5 cm in diameter), renal vein (0.5 cm in length, x 0.2 cm in diameter), renal artery (2.6 cm in length x 0.6 cm in diameter), and attached yellow/tan perinephric adipose tissue (up to 3.5 cm in thickness). The specimen is bivalved. In the lower pole, 8.5 cm from the ureteral margin, 4.9 cm from the renal artery margin, and 3.5 cm from the renal vein margin, there is a well encapsulated yellow/red hemorrhagic centrally fibrotic mass (8.7 x 7.4 x 5.7 cm) compressing and distorting the renal parenchyma and the renal capsule. Upon sectioning, the mass is approximately 90% solid and 10% cystic. The mass comes to within 0.3 cm of the blue inked deep/perinephric fat margin. The mass focally compresses and distorts but does not grossly appear to invade into the inferior pelvocaliceal system and renal sinus.

The uninvolved kidney parenchyma is tan/brown with a moderately distinct cortical medullary junction and approximately six smooth walled tan simple cortical cyst (ranging from 0.7 to 3.5 cm in greatest dimension) scattered throughout the mid and superior poles. Each of the cysts is filled with clear serous fluid, with no excrescences grossly identified. The pelvocaliceal system is moderately dilated and exhibits smooth glistening tan mucosa. The adrenal gland (6.2 x 2.5 x 1.2 cm) is present and exhibits an unremarkable golden yellow cortex (0.2 cm in maximum thickness) and red/brown medulla (0.1 cm in maximum thickness).

[page 2 of 3]
[REDACTED]

examined. There is no evidence of active glomerulitis, proliferative lesions or fibrinoid necrosis.

The kidney parenchyma has been reviewed by Dr. [REDACTED] Renal Pathologist.

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin-embedded tissue (block A8) were evaluated using HE, PAS, Jones silver methenamine, and AFOG (trichrome) stains.

The sample consists of cortex and medulla. There are 155 glomeruli present, of which 16 (10.3 %) are globally sclerosed. The remaining glomeruli show mild signs of hypertrophy of the tuft. There is very mild, focal expansion of the mesangial areas. On PAS and Jones silver stains there are no discernible crater-like defects or "spikes", and only isolated double contours of the glomerular capillary wall basement membranes are recognized. Several distal tubules contain PAS-positive hyaline casts. Isolated distension of tubules is recognized in the cortical area. Approximately 5% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis as seen in the trichrome stain (AFOG). Arteries and arterioles exhibit moderate degree of sclerosis, with focal hyaline accumulation in the subintima in the arterioles.

[REDACTED]

[page 3 of 3]
Pathology Report

Accession Number: [REDACTED]

Report Status: Final

Type: Cytogenetics

CASE: [REDACTED]

PATIENT: [REDACTED]

Cytogeneticist: [REDACTED]

KARYOTYPE: 46,XY[15]

METAPHASES COUNTED: 15

ANALYZED: 5

SCORED: 10

BANDING: GTG

INTERPRETATION:

No cytogenetic aberrations were identified in metaphases analyzed from this specimen. This normal result does not exclude a neoplastic proliferation.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

RCC

[REDACTED]

Source: NCI Genomic Data Commons file b459cc7f-b164-4dfc-b664-4d0a2a5ffc1c (TCGA-CZ-5451.7809316E-40A5-442A-BB0D-9C175F08D38B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).